Somatic mutation profile of tumor specimen TCGA-QH-A65S-01A (aliquot TCGA-QH-A65S-01A-11D-A29Q-08) from TCGA case TCGA-QH-A65S, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 32.5 years (11,861 days).
Specimen TCGA-QH-A65S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bec77d6-945b-412e-b6ad-9e98231970df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A65S-10A (Blood Derived Normal), aliquot TCGA-QH-A65S-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c77b8de3-4d6d-4ad3-b088-e802186d291f

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPG | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs577584936, COSV54966700; called by muse, mutect2, varscan2
- ANO1 | c.368A>G p.D123G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV60286295; called by muse, mutect2
- ATP9A | c.451A>C p.K151Q | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV58768393; called by muse, mutect2, varscan2
- BSG | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.941); catalogued as COSV61077549; called by muse, mutect2, varscan2
- C6orf15 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768494710, COSV52538789; called by muse, mutect2, varscan2
- EPG5 | c.2648A>G p.N883S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as rs767545552, COSV56351727; called by muse, mutect2, varscan2
- FGF5 | c.548A>T p.K183I | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV56890719; called by muse, mutect2, varscan2
- FLNB | c.4525G>A p.V1509I | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV55884038; called by muse, mutect2, varscan2
- HSD3B7 | c.602T>G p.I201S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV52680904; called by muse, mutect2, varscan2
- OR52A5 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56614425, COSV56615740; called by muse, mutect2
- PCDH19 | c.995T>C p.V332A | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55265892; called by muse, mutect2, varscan2
- TPTE2 | c.764A>G p.K255R (on ENST00000400230 / NM_199254.2; = p.K178R on NM_130785.3) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV55023685; called by muse, mutect2, varscan2
- VCAN | c.4489G>C p.E1497Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54108662; called by muse, mutect2, varscan2
- ATRX | c.4076del p.K1359Sfs*16 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- TP53 | c.1035dup p.E346* | Frame Shift Ins (INS) | VAF 14/29 reads (48%) | called by mutect2, pindel, varscan2
- AMER1 | c.720T>C p.S240= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as COSV57662749; called by muse, mutect2, varscan2
- CHMP1A | c.22T>C p.L8= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as COSV53683657; called by muse, mutect2, varscan2
- OPN4 | c.459T>C p.F153= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV54117226; called by muse, mutect2, varscan2
- RPIA | c.771C>T p.I257= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV52170322; called by muse, mutect2, varscan2
- SETMAR | c.747C>G p.A249= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs1176573145, COSV62780458, COSV62781059; called by muse, mutect2, varscan2
